Gene-level copy-number profile of tumor specimen TCGA-CN-A63U-01A from TCGA case TCGA-CN-A63U, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 50.0 years (18,272 days).
Specimen TCGA-CN-A63U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.1687245a-4164-48f7-9f55-5d9536e16518.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-A63U-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ea7caa1c-246e-4575-a4ba-1fe7f4ac8dfc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 306; copy number 2: 14,423; copy number 3: 19,040; copy number 4: 19,282; copy number 5: 3,473; copy number 6: 2,011; copy number 7: 504; copy number 8: 665; copy number 10: 2; copy number 12: 8; copy number 15: 10; copy number 19: 47; copy number 29: 43.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-A63U-01A-11D-A30D-01): tumor purity 0.72, ploidy 1.78, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 110 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:44,793,119–44,959,709, 2 genes, copy number 10 (within-gene range 2–10): TMEM72-AS1, EIF2AP4.
- chr15:26,395,037–26,970,385, 8 genes, copy number 12: LINC02248, AC009878.2, GABRB3, AC009878.1, AC011196.1, AC135999.1, GABRA5, TVP23BP1.
- chr18:47,390–4,459,458, 100 genes, copy number 15–29 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 306. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
